Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABON, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABON-TTP1-A (Primary Tumor).

[page 1 of 10]
+0

Pathology Report: DISTAL MESENTERIC NODULE.

Provider:

Location

DISTAL MESENTERIC NODULE.

CASE:

ORDERING PROVIDER:

**** THIS IS AN ADDENDUM REPORT ****

*****Addendum *****

LOCATION:

SPECIMEN(S) :

1. DISTAL MESENTERIC NODULE.
2. PROXIMAL ILEUM NODULE.
3. JEJUNUM NODULE.
4. PROXIMAL JEJUNUM NODULES X 3.
5. LATERAL RIGHT WALL INFLAMATION.
6. RIGHT COLON.

CLINICAL HISTORY RLQ PAIN.

FINAL DIAGNOSIS:

Nodular lesion, distal mesentery soft tissue, excisional biopsy (specimen #1):

- adenocarcinoma, mucinous type, with necrosis; forming a 0.7 cm diameter metastatic tumor implant.

Nodular lesion, proximal ileum soft tissue, excisional biopsy (specimen #2):

- adenocarcinoma, mucinous type, with necrosis; forming a 1.2 cm diameter metastatic tumor implant.

Nodular lesion, jejunum soft tissue, excisional biopsy (specimen #3):

- adenocarcinoma, mucinous type, with necrosis; forming two metastatic tumor implants 0.4 cm and 0.5 cm in greatest dimension.

Nodular lesions, proximal jejunum soft tissue, excisional biopsies (specimen #4):

- adenocarcinoma, mucinous type, with necrosis; forming three metastatic tumor implants 0.9 cm, 1.2 and 1.6 cm in greatest dimension.

Inflammatory lesion, right lateral wall, biopsy (specimen #5):

- acute microabscess with fibrosis and granulation tissue formation.
- negative for metastatic carcinoma.

Mass lesion, right colon, hemicolectomy (specimen #6):

- Tumor Type: Adenocarcinoma, invasive, mucinous type.
- Histologic Tumor Grade: Poorly differentiated; grade III (of IV).

[page 2 of 10]
- Tumor Location: Cecal pouch.
- Gross Configuration of Tumor: Ulcerating and deeply infiltrative.
- Pre-existing Polyp (at site of carcinoma): No evidence of a pre-existing polyp.
- Tumor Size: 3.7 x 3.1 x 1.6 cm by gross examination.
- Tumor Perforation: Microscopic foci of highly necrotic tumor with acute abscess formation; suspicious for tumor perforation.
- Angiolymphatic Tumor Involvement: Positive.
- Perineural Tumor Involvement: Positive.
- Surgical Margins: The proximal ileal and distal colonic transverse surgical resection margins are grossly and microscopically negative for tumor involvement; the deep radial pericecal fatty ink-stained surgical resection margin is microscopically negative for tumor involvement.
- Free Peritoneal Surface: The free serosal surface of the colon is positive for tumor emboli in subserosal lymphatics associated with hemorrhage and necrosis.
- Appendix: The cecum at the appendiceal orifice is microscopically negative for tumor involvement.
- Regional Lymph Nodes in Pericecal Fibroadipose Tissue:
- a. Total number of lymph nodes examined: 12.
- b. Number of lymph nodes positive for metastatic carcinoma: 1.
- Non-neoplastic Bowel: Not otherwise unremarkable.

Pathologic staging (AJCC, 6th edition): pT4, pN1, pM1.

GROSS:

Specimen #1 is received in formalin labeled "distal mesenteric nodule" and consists of a 1.0 x 0.8 x 0.5 cm gray-white rubbery nodule. The specimen is bisected and is entirely submitted in cassette 1A.

Specimen #2 is received in formalin labeled "proximal ileum nodule" and consists of a 1.2 x 1.2 x 0.6 cm gray-white rubbery nodule. The specimen is bisected and the entire specimen is submitted in cassette 2A.

Specimen #3 is received in formalin labeled "jejunum nodule" and consists of a 0.9 x 0.6 x 0.4 cm gray-white rubbery nodule. The specimen is bisected and the entire specimen is submitted in cassette 3A.

Specimen #4 is received in formalin labeled "proximal jejunum nodules x 3" and consists of three gray-white rubbery nodules, ranging from 1.0 cm to 2.6 cm in greatest dimension. The entire specimen is submitted as follows: cassette 4A - smallest nodule trisected; 4B - next smallest nodule trisected; 4C to 4E - entire larger nodule sectioned.

Specimen #5 is received in formalin labeled "lateral right wall inflammation" and consists of a 1.0 x 0.6 x 0.3 cm tan-gray wrinkled hemorrhagic portion of soft tissue. The specimen is submitted intact and entirely in cassette 5A.

Specimen #6 is received in formalin labeled "right colon" and consists of a right hemicolectomy specimen, including a 10.0 cm segment of

[page 3 of 10]
[REDACTED]

terminal ileum, cecum with appendix, and a 5.9 cm segment of ascending colon. The serosal surface is pink-tan, smooth and unremarkable with adherent tan-yellow lobulated pericolonic fat. In the cecal area, the pericolonic fat is red-brown and hemorrhagic with an abundant amount of tan-white fibrinous exudate. The appendix is adherent to the pericolonic fat and exudate. The mucosa of the cecum shows a 3.7 x 3.1 x 1.6 cm pink-red ulcerated tumor mass with rolled edges. This tumor mass does not involve the appendiceal orifice and is located 0.6 cm from the ileocecal valve, 9.6 cm from the proximal resection margin and 7.2 cm from the distal resection margin. The radial margin of the cecum is inked black. Sections through the mass show the mass to extend through the entire cecal wall, into the pericecal fat and abut against the black ink-stained radial margin. The cecal fat in the area of the tumor is indurated and slightly necrotic. The tumor involves approximately 85% of the cecal pouch. The remaining cecal mucosa is unremarkable. The terminal ileum, ileocecal valve and ascending colon are all unremarkable with no masses or lesions identified. The appendix is 6.8 cm in length and 0.6 cm in diameter. The serosal surface is tan-gray, smooth and unremarkable. Sections through the appendix show the lumen to measure 0.2 cm in diameter; it is unremarkable with no masses, lesions or perforations identified. Separate in the specimen container is a 3.2 cm segment of unoriented bowel with a pink-tan smooth unremarkable serosa. The mucosal surface of this segment is unremarkable. A total of 13 lymph nodes are found in the pericolonic fat, ranging from 0.6 cm to 1.5 cm in greatest dimension. A few of the lymph nodes are tan-white and indurated and features suspicious for tumor involvement.

Representative sections are submitted as follows: cassette 6A - proximal resection margin en face; 6B - distal resection margin en face; 6C to 6F - sections of tumor to black inked radial margin; 6G - tumor to appendiceal orifice; 6H - tumor to normal cecal mucosa; 6I - normal terminal ileum; 6J - section of ileocecal valve; 6K - sections of normal ascending colon; 6L - longitudinal section of distal tip of appendix; 6M - additional sections of appendix; 6N - resection margins en face of separate segment of bowel; 6O - additional sections of separate fragment of bowel; 6P to 6R - each contain one bisected lymph node that is possibly positive; 6S and 6T - one possibly positive lymph node sectioned; 6U - one lymph node bisected; 6V - one lymph node bisected; 6W - four lymph nodes intact; 6X - three lymph nodes intact.

The gross specimen is reviewed with [REDACTED]

[REDACTED]

MICROSCOPIC:

Microscopic finding(s) correspond to the diagnosis(es) given above.

Final Diagnosis issued by [REDACTED] Electronically signed [REDACTED]

[page 4 of 10]
ADDENDUM REPORT:

This case is reviewed follow receipt of [REDACTED] KRAS mutation analysis requested by [REDACTED] and performed on this patient's adenocarcinoma of the cecum. Pathology received this report via fax transmission of [REDACTED] +25

[REDACTED] test results: No mutation detected.

[REDACTED] interpretation: No mutations were identified at codons 12 and 13 of the KRAS gene.

[REDACTED] comment: Mutations in the KRAS gene are reported to be associated with resistance to anti-EGFR monoclonal antibody therapies in patients with colorectal cancer. KRAS mutations occur in 30-60% of colorectal adenocarcinomas.

Please see [REDACTED] specimen report # [REDACTED] for additional details.

[REDACTED]
Addendum #1 issued by [REDACTED] Electronically signed

+25

Signed before import by [REDACTED]
Filed automatically on [REDACTED] +25
Electronically Signed by [REDACTED]

[page 5 of 10]
+25

Imaging Report: PET COLORECTAL CANCER INITIAL STAGING

Provider: [REDACTED]

Location of Care: [REDACTED]

This document contains external references

PET COLORECTAL CANCER INITIAL STAGING

ORDERING PROVIDER: [REDACTED]

MR#: [REDACTED]

INDICATION: COLON CANCER

NUCLEAR MEDICINE PET CT EXAMINATION

COMPARISON: None.

CLINICAL

HISTORY: Colon carcinoma.

TECHNIQUE: Following the intravenous administration of 17.2 mCi of 18 fluorodeoxyglucose radiopharmaceutical, whole body multiplanar PET examination provided from mid brain to the proximal aspects of the lower extremities, without correlative CT imaging in this region, without contrast material otherwise administered. Blood glucose level 118 mg/dl.

FINDINGS: There is moderate to marked increase symmetrical uptake, within the pharyngeal, oropharyngeal regions, representing the physiologic uptake. There is a small subcentimeter lymph node, within the right superior mediastinum just posterior to the right thyroid lobe, which demonstrated marked increased uptake radiopharmaceutical measuring 3.1 SUV. Also marked uptake radiopharmaceutical exists within the subcentimeter precarinal lymph node. There is marked increased uptake radiopharmaceutical present within mesenteric nodule, within the left upper quadrant anteriorly with SUV measuring 17. Additionally, there is region of amorphous increased density. No definite mass, within the periumbilical region, and marked increased uptake radiopharmaceutical does exist at this location measuring 4.4 SUV.

Additionally, marked increased uptake of radiopharmaceutical exists in curvilinear right distribution, at the subcutaneous, left paramidline region of the pelvic wall, at surgical incisional site representing inflammatory changes as well. At region just medial to the surgical incision site, of the cecal region, is amorphous and nodular and soft tissue density with marked increased uptake of radiopharmaceutical, measuring approximately 4.5 to 7.1 SUV. There are multiple subcentimeter diameter of asymmetrically minimally prominent lymph nodes of the posterior aspect of the deep portion of the parotid gland right side, with marked SUV associated measuring 7.9. These are all subcentimeter in diameter with largest lymph node measuring 8 mm short axis diameter.

IMPRESSION:

1. Marked increased metabolic activity, nodule prominence at region of the cecal and pericecal location consistent with recurrent or

PR

[page 6 of 10]
[REDACTED]

[REDACTED]

[REDACTED]

residual carcinoma at this location.

2. Peritoneal nodule left upper quadrant, marked increased metabolic activity highly suspicious for early peritoneal carcinomatosis.

3. Markedly metabolically active lymph nodes, within the mediastinum (right superior, and precarinal regions) suspicious for malignant neoplastic change (either lymphangitic spread of carcinoma from patient's history of colon carcinoma with unusual distribution, versus possible secondary lymphoma).

4. Markedly metabolic active lymph nodes, within the right parotid gland region again suspicious for lymphangitic spread of carcinoma in unusual distribution from colon carcinoma, versus possible secondary lymphoma.

5. Inflammatory change, of the periumbilical, pelvic wall region likely postsurgical change and/or superimposed inflammatory or infectious etiologies. [REDACTED] was notified of the findings by email at time of dictation.

CC:

DICTATED BY: [REDACTED]

SIGNED BY: [REDACTED]

External Attachment:

Type: Image
Comment: PACS IMAGE

Signed before import by [REDACTED]
Filed automatically on [REDACTED] +28
Electronically Signed by [REDACTED]

[page 7 of 10]
+268 [REDACTED] Imaging Report: CT ABDOMEN W/ CONTRAST

Provider: [REDACTED]

Location of Care: [REDACTED]

This document contains external references

CT ABDOMEN W/ CONTRAST

ORDERING PROVIDER: [REDACTED]

MR#: [REDACTED]

INDICATION: COLON CANCER NODULAR DENSITY RIGHT LOWER LUNG

CT SCAN CHEST WITH IV CONTRAST:

HISTORY: This is a 65 year old patient. Patient has a history of metastatic colon cancer. Patient was diagnosed in [REDACTED] +0
Patient presented with an "inflammatory process" in the cecal region. Patient was ultimately found to have a colon cancer arising from the cecum. Patient underwent a right hemicolectomy. At the time of surgery, patient had removal of six metastatic implants. Patient had at least one node which was abnormal. Patient has been treated with chemotherapy. This is a follow-up study.

TECHNIQUE: CT scan of the chest is done. 3.75 mm with IV contrast. I have the earlier PET CT scan of [REDACTED] for correlation.

+25

+25

FINDINGS: There are some small nodes that are identified in the mediastinum especially in a pretracheal location and in the AP window region. These nodes are not felt to be changed significantly compared with [REDACTED] Did show minimal increased activity on an earlier PET scan. I would suspect that these nodes probably are more likely on a reactive or inflammatory basis. I do not see any enlarging mediastinal, hilar or axillary lymphadenopathy compared with before. There are no pleural effusions. There is some atelectasis that is identified posteriorly within the upper and lower lungs. There is a more focal area of consolidation that is identified posteriorly within the right lower lobe on image #51. This has a somewhat whorled appearance and I think this represents an area of atelectasis rather than a pulmonary nodule or mass. I do not feel that there are any definite nodules or masses on the study that would suggest metastatic disease. The appearance of the right lower lobe in particular will need to be followed on subsequent scans to ensure that it does not grow however. Bone window images are reviewed. There is some generalized degenerative end plate change and spurring. I do not see a worrisome lytic or blastic lesion. Patient has some mild compression deformities throughout the mid and lower thoracic spine though I do not necessarily feel that is an acute compression fracture.

IMPRESSION:

1. Known history of metastatic colon cancer with known history of peritoneal implants of disease as well as known history of lymph node involvement at the time of surgery.

[page 8 of 10]
[REDACTED] [REDACTED]
[REDACTED]
2. No convincing metastatic disease to the chest is identified.
There is no worrisome mediastinal or hilar lymphadenopathy.
3. A probable rounded area of atelectasis is identified within the
posterior aspect of the right lower lobe. Otherwise, no worrisome
pulmonary nodules or masses are identified.
CT SCAN ABDOMEN WITH IV AND ORAL CONTRAST:

+0

HISTORY: Follow-up colon cancer. Patient was diagnosed in
[REDACTED] Patient had a previous right hemicolectomy done.
Patient has a history of peritoneal implants of disease. Patient has
a history of lymph node involvement. Patient has been treated with
chemotherapy.

TECHNIQUE: CT scan of the abdomen is done. 3.75 mm slices with IV
and oral contrast.

My comparison study is a PET CT scan of [REDACTED] +25

FINDINGS: Patient had an implant of disease that was identified in
particular within the left upper quadrant on [REDACTED] This area +25
showed marked increased activity on a PET scan at that time. I think
that implant has become smaller. I cannot confidently identify that
implant on today's study. By history, this patient is post right
hemicolectomy. I can identify an anastomosis site with the right
lower abdomen. I see no obvious recurrent or residual mass at the
anastomosis site to suggest that there is a local recurrence of
disease. I do not see any definite implants of disease within the
remainder of the abdomen by this study.
The liver looks homogeneous without metastases.
There has been an interval increase in size of the spleen compared
with before. The spleen has much more bulbous, globular appearance
compared with before. The spleen itself measures about 17 cm in
craniocaudal dimension. The spleen does look homogeneous without
focal mass however. The gallbladder is normal. The pancreas is
normal. Adrenals are normal. Right and left kidneys show no
significant abnormalities. Patient has an extrarenal pelvis
especially on the right side though this appearance is regarded as a
normal variant. Patient has some underlying atherosclerotic changes
related to the abdominal aorta. I do not feel there is aneurysmal
dilatation. I do not see worrisome abdominal or retroperitoneal or
mesenteric lymphadenopathy. Patient has had previous midline
surgery. There is some bulging of the fascia at the surgical site
though there is no frank dehiscence of the fascia.

IMPRESSION:

+25

1. Post right hemicolectomy for cecal cancer as above. Patient
apparently had peritoneal implants at the time of surgery. There is
at least one dominant implant identified in the left upper abdomen on
[REDACTED] I do not definitely see this implant on today's study.
I see no other definite implants of disease on today's study.
2. There has been an interval enlargement in the spleen size
compared with [REDACTED] The spleen is estimated to be about 17 cm
in size on today's study. +25
3. Otherwise, I do not see any other significant abnormalities
within the remainder of the abdomen.
CT SCAN PELVIS WITH IV AND ORAL CONTRAST:

[page 9 of 10]
[REDACTED]

[REDACTED]

[REDACTED]

HISTORY: Follow-up colon cancer.

TECHNIQUE: 3.75 mm slices with IV and oral contrast.

My comparison study is the PET CT scan of [REDACTED] +25

FINDINGS: As before, patient has bilateral spondylolysis defect related to the posterior elements of L5. There is minimal associated anterolisthesis of L5 on S1. This is a chronic finding. There is some degenerative change in the facet joints. I see no worrisome lytic or blastic lesions.

Within the pelvis, patient has some underlying atherosclerotic changes related to a nondilated iliac system. The prostate is mildly enlarged with some prostatic calcifications. Otherwise, no unusual masses or fluid collections. No worrisome adenopathy.

IMPRESSION:

1. No evidence for metastatic disease to the pelvis.
2. Mild enlargement of the prostate.
3. Known bilateral spondylolysis defect that is related to the posterior elements of L5.
4. Otherwise, no significant change compared with an earlier PET CT of [REDACTED] +25

CC:

Dictated by: [REDACTED]

Signed by: [REDACTED]

External Attachment:

Type: Image
Comment: PACS IMAGE

Signed before import by [REDACTED]
Filed automatically on [REDACTED] +268
Electronically Signed by [REDACTED]

[page 10 of 10]
Patient Information

Results

CT ABDOMEN PELVIS WITH CONTRAST (Order

Collection Information

Collected: +1661

Comments

Colon Cancer Surveillance

Result Date - +1662

Result Narrative

CT SCAN OF THE ABDOMEN AND PELVIS WITH CONTRAST

HISTORY: Colon cancer surveillance.

TECHNIQUE: Axial images are obtained from the lung bases to the pubic symphyses after the administration of oral and intravenous contrast. Intravenous contrast dose is not indicated.

COMPARISON: Comparison CT of the chest, abdomen and pelvis

FINDINGS: +1290

CT ABDOMEN: There is dependent atelectasis in both posterior lung bases. There is a stable area of rounded nodularity adjacent to the pleura in the right lower lung which measures 1.2 x 1.1 (I-13).

Cardiac size is within the range of normal.

The liver, spleen, pancreas, and right adrenal are grossly normal.

There is a 1.0 cm lesion in the left adrenal gland (I-39 to 113) which contains macroscopic fat, likely an adenoma or small myelolipoma. The kidneys enhance symmetrically without obstructive changes. There is small to moderate hiatal hernia present. No adenopathy is appreciated.

IMPRESSION:

1. Stable left adrenal mass, likely an adenoma or myelolipoma.
2. Rounded pleural based density adjacent to the right lower lung which remains stable.
3. Otherwise grossly unremarkable CT abdomen.

CT PELVIS: There is a focal area of probable omental infarct associated with the mesentery of the proximal transverse colon (I-49), which measures 1.7 x 1.6 cm. In retrospect this was present on the prior study. There is slight mural thickening of the ascending and transverse colon with inflammatory changes in the mesentery which appear stable. There is diverticulosis without evidence of diverticulitis present. No pelvic masses are appreciated. No adenopathy is noted. Bilateral patent inguinal rings are present. Osseous structures appear grossly intact.

IMPRESSION:

1. Slight mural thickening of the ascending and transverse colon, which could indicate colitis.
2. No evidence of recurrent disease or metastatic malignancy.

Linked Documents

View Image

Source: NCI Genomic Data Commons file 9ea5bcc3-9b23-4113-842b-ab44763cb66d (ER0176 ER-ABON Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).